Somatic mutation profile of tumor specimen 0E0A08 from CCDI case PBCUWP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E0A08: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6f45145-6c3a-4360-a76d-d8f1e0078c7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0A0L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d8ef5c8-34b3-4d6f-8f23-00c4193a0630

The open-access MAF lists 53 somatic variants for this specimen: 39 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 8, Intron 4, Nonsense Mutation 3, 5'UTR 1, 3'UTR 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 367/1064 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 137/1485 reads (9%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 956/1096 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY10 | c.3619C>T p.R1207W | Missense Mutation (SNP) | VAF 594/1379 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs147104989; called by muse, mutect2, varscan2
- AMDHD1 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 358/937 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs1265326451, COSV57140203; called by muse, mutect2, varscan2
- CACNA1B | c.1589C>G p.S530C | Missense Mutation (SNP) | VAF 95/1571 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.87); catalogued as COSV53148899; called by muse, mutect2
- CACNA1B | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 45/451 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1480309391; called by muse, mutect2, varscan2
- CDX1 | c.685C>A p.H229N | Missense Mutation (SNP) | VAF 29/479 reads (6%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.013); catalogued as rs1276735822; called by muse, mutect2
- FAM117A | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 132/1766 reads (7%) | catalogued as rs753601420, COSV53630534; called by muse, mutect2
- HOXA10 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 47/439 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as rs1378155569; called by muse, mutect2, varscan2
- HYDIN | c.12245C>T p.P4082L | Missense Mutation (SNP) | VAF 256/942 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754974697; called by muse, mutect2, varscan2
- ITK | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 172/794 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs886060327, COSV101439961, COSV70062082; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1523C>A p.A508E | Missense Mutation (SNP) | VAF 50/859 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.103); catalogued as rs145554825, COSV100310790; called by muse, mutect2
- KHNYN | c.-18+12_-18+13dup | Splice Region (INS) | VAF 70/216 reads (32%) | catalogued as rs978342310; called by mutect2, varscan2
- L3MBTL1 | c.598G>A p.A200T (on ENST00000418998 / NM_001377303.1; = p.A110T on NM_015478.7) | Missense Mutation (SNP) | VAF 96/1631 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1478588605, COSV64230762; called by muse, mutect2
- MAGEL2 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 145/1564 reads (9%) | SIFT deleterious, low confidence (0.01); catalogued as rs1359447999; called by muse, mutect2
- MKRN3 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 79/1003 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as CM1512776; called by muse, mutect2
- PCDH11Y | c.3136C>T p.R1046W | Missense Mutation (SNP) | VAF 260/405 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99290362; called by muse, mutect2, varscan2
- PDE6B | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 66/735 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs775472684; called by muse, mutect2
- ZBED5 | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 119/1141 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1285704503; called by muse, mutect2, varscan2
- CARS1 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 94/1064 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2
- CARS1 | c.1263G>C p.L421F | Missense Mutation (SNP) | VAF 88/1184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COA7 | c.87C>A p.Y29* | Nonsense Mutation (SNP) | VAF 62/665 reads (9%) | called by muse, mutect2
- DCHS1 | c.1877C>G p.S626C | Missense Mutation (SNP) | VAF 71/661 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- DDX58 | c.1680G>A p.M560I | Missense Mutation (SNP) | VAF 314/1831 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EXOC2 | c.1004T>A p.L335* | Nonsense Mutation (SNP) | VAF 89/1115 reads (8%) | called by muse, mutect2
- IL9R | c.607G>C p.G203R | Missense Mutation (SNP) | VAF 401/1310 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MACF1 | c.16496T>C p.L5499S (on ENST00000372915; = p.L3541S on NM_012090.5) | Missense Mutation (SNP) | VAF 82/1210 reads (7%) | called by muse, mutect2
- MUC16 | c.38456A>T p.Q12819L | Missense Mutation (SNP) | VAF 68/1097 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2
- MUC5B | c.7600G>A p.A2534T | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO1B | c.1208T>G p.I403S | Missense Mutation (SNP) | VAF 807/1686 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- NKX6-1 | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 44/456 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2
- OR51G2 | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 83/770 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLEKHG2 | c.629dup p.P211Afs*124 | Frame Shift Ins (INS) | VAF 262/682 reads (38%) | called by mutect2, varscan2
- POLDIP3 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 100/1238 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- PRRX2 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 252/632 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM51GP | c.923G>A p.S308N | Missense Mutation (SNP) | VAF 281/1192 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- TRPM5 | c.881A>G p.E294G | Missense Mutation (SNP) | VAF 65/844 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.011); called by muse, mutect2
- U2AF2 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 271/701 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS16 | c.2397G>A p.G799= | Silent (SNP) | VAF 114/948 reads (12%) | catalogued as rs772756646; called by muse, mutect2, varscan2
- BBS5 | c.399T>A p.T133= | Silent (SNP) | VAF 37/1463 reads (3%) | called by muse, mutect2
- LSM10 | c.111C>T p.S37= | Silent (SNP) | VAF 95/677 reads (14%) | catalogued as rs147246296; called by muse, mutect2, varscan2
- LSMEM1 | c.180G>A p.R60= | Silent (SNP) | VAF 45/1394 reads (3%) | called by muse, mutect2
- MUC5AC | c.3522C>T p.C1174= | Silent (SNP) | VAF 96/666 reads (14%) | called by muse, mutect2
- NOTCH1 | c.5091C>T p.T1697= | Silent (SNP) | VAF 153/1186 reads (13%) | catalogued as rs775882968, COSV99488178; called by muse, mutect2, varscan2
- STXBP2 | c.1299G>A p.A433= | Silent (SNP) | VAF 62/970 reads (6%) | catalogued as rs542699433, COSV55404505; ClinVar: likely benign; called by muse, mutect2
- TRAPPC6A | c.423C>T p.T141= (on ENST00000585934 / NM_001270891.2; = p.T155= on NM_024108.3) | Silent (SNP) | VAF 298/728 reads (41%) | catalogued as rs1414675269; called by muse, mutect2, varscan2
- DIS3L2 | c.2394+78G>A | Intron (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- ENY2 | c.229+83T>C | Intron (SNP) | VAF 37/530 reads (7%) | called by muse, mutect2
- FAM3C | c.-5C>A | 5'UTR (SNP) | VAF 109/1756 reads (6%) | called by muse, mutect2
- IFNAR2 | c.841-140G>A | Intron (SNP) | VAF 41/729 reads (6%) | catalogued as rs777305113; called by muse, mutect2
- PRR29 | c.243+50C>T | Intron (SNP) | VAF 22/190 reads (12%) | called by muse, mutect2, varscan2
- SLC45A4 | c.*62C>T | 3'UTR (SNP) | VAF 107/1370 reads (8%) | called by muse, mutect2
